Somatic mutation profile of tumor specimen TCGA-HC-7232-01A (aliquot TCGA-HC-7232-01A-11D-2114-08) from TCGA case TCGA-HC-7232, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.6 years (24,324 days).
Specimen TCGA-HC-7232-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22f6df90-03e0-4788-8a68-b4deb295e09c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7232-10A (Blood Derived Normal), aliquot TCGA-HC-7232-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4ea0ec0-1313-430a-bd02-fd101342565b

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, 3'UTR 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHSG | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as COSV56607270; called by muse, mutect2, varscan2
- ALDH1L1 | c.2605G>C p.A869P | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56419867; called by muse, mutect2, varscan2
- ASTL | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs199510888, COSV60905260; called by muse, mutect2, varscan2
- CCNG2 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs985719287, COSV60354867; called by muse, mutect2, varscan2
- COL7A1 | c.2249C>T p.T750M | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs377763372; called by muse, mutect2, varscan2
- DDX47 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV61912169; called by muse, mutect2, varscan2
- DISP3 | c.3865G>A p.V1289M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs545099796, COSV53838508; called by muse, mutect2, varscan2
- ENOX1 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1299385078, COSV54889073, COSV54914203; called by muse, mutect2, varscan2
- EXT2 | c.1117G>A p.V373M (on ENST00000343631; = p.V406M on NM_000401.3) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs750547674, COSV59155748; called by muse, mutect2, varscan2
- GAB2 | c.419C>T p.S140F (on ENST00000361507 / NM_080491.3; = p.S102F on NM_012296.3) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs767427723, COSV60871383; called by muse, mutect2, varscan2
- KIF2B | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779737986, COSV52126920, COSV52127326; called by muse, mutect2, varscan2
- MAGEA6 | c.684A>C p.L228F | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61449538; called by muse, mutect2
- PTCHD4 | c.2467G>A p.A823T | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.309); catalogued as rs761782656, COSV59798522; called by muse, mutect2, varscan2
- RFTN1 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61923865; called by muse, mutect2, varscan2
- THAP4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV67191205; called by muse, mutect2
- TNXB | c.12214G>A p.V4072M (on ENST00000647633; = p.V3825M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs550641852, COSV64481562; called by muse, mutect2, varscan2
- UHRF1 | c.515C>G p.S172C (on ENST00000612630 / NM_001290050.1; = p.S185C on NM_013282.4) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV53577211; called by muse, mutect2, varscan2
- VPS16 | c.2249A>G p.K750R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs774178811, COSV66799598; called by muse, mutect2, varscan2
- ZCWPW1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV61250692; called by muse, mutect2, varscan2
- ZFP36L1 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60547383; called by muse, mutect2, varscan2
- PPP4R3A | c.1898_1932del p.Y633* (on ENST00000554943 / NM_001366432.1; = p.Y620* on NM_001284280.1) | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel
- AP2M1 | c.1242C>T p.S414= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs778990308, COSV53050036; called by muse, mutect2, varscan2
- F8 | c.1896C>T p.I632= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as rs868931246, COSV64279219; called by muse, mutect2
- GZMB | c.558G>A p.E186= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs150419134; called by muse, mutect2, varscan2
- HMCN1 | c.3270C>T p.S1090= | Silent (SNP) | VAF 74/280 reads (26%) | catalogued as rs761064415, COSV54877415; called by muse, mutect2, varscan2
- OR5F1 | c.438C>T p.A146= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs756447954, COSV53545224, COSV99558526; called by muse, mutect2, varscan2
- PLAT | c.426G>T p.A142= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV54278455; called by muse, mutect2, varscan2
- PTPRK | c.4140C>T p.G1380= (on ENST00000368215 / NM_001291984.2; = p.G1381= on NM_002844.4) | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs375248533; called by muse, mutect2, varscan2
- SUSD2 | c.1077G>A p.R359= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV64205497; called by muse, mutect2, varscan2
- TOX2 | c.240G>A p.P80= (on ENST00000358131 / NM_001098798.2; = p.P29= on NM_032883.3) | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs774698912, COSV57881921; called by muse, mutect2, varscan2
- ZIC5 | c.1344G>A p.E448= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV57439107; called by muse, mutect2, varscan2
- LRRC49 | c.-2T>G | 5'UTR (SNP) | VAF 27/157 reads (17%) | catalogued as COSV51437294; called by muse, mutect2, varscan2
- TRIM10 | c.*230C>T | 3'UTR (SNP) | VAF 4/62 reads (6%) | catalogued as COSV65000233; called by muse, mutect2
